FM case AD1181 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/e2f25246-35c9-4cd0-b9c8-1189e1d819cf

Male, 65.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); metastasis biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
